Somatic mutation profile of tumor specimen TCGA-A4-7288-01A (aliquot TCGA-A4-7288-01A-11D-2136-08) from TCGA case TCGA-A4-7288, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 71.9 years (26,268 days).
Specimen TCGA-A4-7288-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 876047c5-dde9-447c-8a30-f0b447d72af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7288-11A (Solid Tissue Normal), aliquot TCGA-A4-7288-11A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a82f257-f6e4-4e89-a1e0-4af175ed3c9d

The open-access MAF lists 73 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 15, Frame Shift Del 5, Splice Site 4, In Frame Del 2, Frame Shift Ins 2, Intron 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.3124T>C p.S1042P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52708675; called by muse, mutect2, varscan2
- ABCC11 | c.1046T>C p.I349T | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62324784; called by muse, mutect2, varscan2
- ACLY | c.1641G>T p.E547D | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV61251907; called by muse, mutect2, varscan2
- AFG3L2 | c.961A>G p.M321V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV52316320; called by muse, mutect2, varscan2
- AHSG | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV56608637; called by muse, mutect2, varscan2
- AQP7 | c.585C>A p.N195K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV53025811; called by muse, mutect2, varscan2
- ARID2 | c.5062-1G>A p.X1688_splice | Splice Site (SNP) | VAF 53/58 reads (91%) | catalogued as COSV57600017; called by muse, mutect2, varscan2
- CTH | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV61009283; called by muse, mutect2, varscan2
- DDI2 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60780576; called by muse, mutect2, varscan2
- DNTTIP2 | c.2021G>T p.R674I | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63284373; called by muse, mutect2, varscan2
- ENTPD6 | c.1045+2T>A p.X349_splice | Splice Site (SNP) | VAF 21/39 reads (54%) | catalogued as COSV61752025; called by muse, mutect2, varscan2
- GALE | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52526770; called by muse, mutect2, varscan2
- HDAC5 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52243387; called by muse, mutect2, varscan2
- HS3ST2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1335261076, COSV54460634; called by muse, mutect2
- IDH2 | c.207+2T>C p.X69_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | catalogued as COSV57478328; called by muse, mutect2
- IGFLR1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1384627254, COSV53075870; called by muse, mutect2, varscan2
- LIMK2 | c.398T>C p.M133T | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs377628882; called by muse, mutect2, varscan2
- LPL | c.1061G>C p.S354T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60932160; called by muse, mutect2, varscan2
- MORC1 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs776364556, COSV51726083; called by muse, mutect2, varscan2
- MUC2 | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs1174230489; called by muse, mutect2, varscan2
- NACC1 | c.1480A>G p.S494G | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV52835356; called by muse, mutect2, varscan2
- NBN | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV55375105, COSV99620206; called by muse, mutect2, varscan2
- NELFA | c.1537G>A p.V513M (on ENST00000542778; = p.V502M on NM_005663.5) | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56393823; called by muse, mutect2, varscan2
- NID2 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as COSV53500083; called by muse, mutect2, varscan2
- NUDC | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs747446963, COSV58325955; called by muse, mutect2, varscan2
- PARP6 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.445); catalogued as COSV53004190; called by muse, mutect2
- PCK2 | c.1014A>C p.E338D | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53749844; called by muse, mutect2, varscan2
- PLEKHA2 | c.652C>A p.R218S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66243179, COSV66243204; called by muse, varscan2
- PPM1A | c.771A>T p.R257S | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57787831; called by muse, mutect2, varscan2
- PRSS8 | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV54898140; called by muse, mutect2, varscan2
- RAB2B | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67235993; called by muse, mutect2, varscan2
- RAB40C | c.832T>C p.C278R | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50194481; called by muse, mutect2, varscan2
- RANBP2 | c.6223A>C p.M2075L | Missense Mutation (SNP) | VAF 234/498 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51705301; called by muse, mutect2, varscan2
- RIF1 | c.3581C>A p.S1194Y | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV54621055; called by muse, mutect2, varscan2
- SCGN | c.780A>T p.K260N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58546450; called by muse, mutect2
- SETDB1 | c.3826G>A p.E1276K (on ENST00000271640 / NM_001366417.1; = p.E1275K on NM_012432.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54988186, COSV54988929; called by muse, mutect2, varscan2
- SGK2 | c.1065A>G p.I355M | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV58314455; called by muse, mutect2, varscan2
- SIGIRR | c.844C>A p.L282M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV58988870; called by muse, mutect2, varscan2
- SLC27A3 | c.2389A>T p.T797S (on ENST00000271857; = p.T669S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV55164903; called by muse, mutect2, varscan2
- TBL1XR1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV61791861; called by muse, mutect2, varscan2
- TCP11L1 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV57516747; called by muse, mutect2, varscan2
- TET2 | c.946T>A p.F316I | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54423676; called by muse, mutect2, varscan2
- TNPO1 | c.2160A>G p.I720M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs1172265335, COSV61523063; called by muse, mutect2, varscan2
- TRAF3IP2 | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60676621; called by muse, mutect2
- TRMT10A | c.968A>G p.K323R | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.036); catalogued as COSV56745736; called by muse, mutect2, varscan2
- UBR1 | c.3210-1G>T p.X1070_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV51933553; called by muse, mutect2, varscan2
- ZNF804A | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV100166833, COSV56461146; called by muse, mutect2, varscan2
- ATL3 | c.855dup p.A286Cfs*3 | Frame Shift Ins (INS) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- C10orf71 | c.384del p.P129Qfs*5 | Frame Shift Del (DEL) | VAF 36/123 reads (29%) | called by mutect2, pindel, varscan2
- CEP135 | c.1649_1657del p.L550_E553delinsQ | In Frame Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- COMMD8 | c.220_222delinsAA p.E74Kfs*6 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by pindel, varscan2*
- HNRNPC | c.689_690del p.N230Rfs*2 (on ENST00000420743; = p.N217Rfs*2 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- PLA2G6 | c.610del p.L204Sfs*10 | Frame Shift Del (DEL) | VAF 25/40 reads (63%) | called by mutect2, pindel, varscan2
- RP1 | c.3657dup p.V1220Cfs*3 | Frame Shift Ins (INS) | VAF 49/128 reads (38%) | called by mutect2, pindel, varscan2
- SPPL2C | c.336_341del p.Q113_G114del | In Frame Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- ZDHHC2 | c.189del p.F63Lfs*17 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- ANKRD44 | c.240G>T p.R80= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV56561066; called by muse, mutect2, varscan2
- APC2 | c.4767C>T p.P1589= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs935601003, COSV52020520; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTG2 | c.45C>T p.A15= | Silent (SNP) | VAF 2/12 reads (17%) | catalogued as rs1424992377, COSV51857005; called by muse, mutect2
- DCP1A | c.214C>A p.R72= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1169884081, COSV53689729; called by muse, mutect2, varscan2
- EMC2 | c.72A>G p.E24= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs1285379491, COSV55210529, COSV99624715; called by muse, mutect2, varscan2
- ESPL1 | c.5652A>G p.T1884= | Silent (SNP) | VAF 118/132 reads (89%) | catalogued as rs760990800, COSV54476615; called by muse, mutect2, varscan2
- IFFO1 | c.1635T>C p.A545= (on ENST00000396840 / NM_001330324.2; = p.A548= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/78 reads (92%) | catalogued as COSV57521726; called by muse, mutect2, varscan2
- INPP5K | c.1056C>G p.T352= | Silent (SNP) | VAF 62/114 reads (54%) | catalogued as COSV100233840, COSV57441934; called by muse, mutect2, varscan2
- MAP3K13 | c.2256G>A p.G752= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as rs1165472011, COSV53993248; called by muse, mutect2
- NDUFS3 | c.705G>A p.L235= | Silent (SNP) | VAF 82/192 reads (43%) | catalogued as COSV55455564; called by muse, mutect2, varscan2
- PLOD2 | c.1185T>A p.V395= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV51467149; called by muse, mutect2, varscan2
- POM121 | c.3747G>A p.K1249= (on ENST00000434423; = p.K984= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV57520692; called by muse, mutect2, varscan2
- SLC12A7 | c.2580G>C p.L860= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV53760006, COSV99370207; called by muse, mutect2, varscan2
- SLC5A12 | c.618T>C p.H206= | Silent (SNP) | VAF 85/209 reads (41%) | catalogued as COSV54823375; called by muse, mutect2, varscan2
- SUGP1 | c.285G>A p.K95= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV55922906; called by muse, mutect2, varscan2
- AP001267.5 | c.-843A>G | 5'UTR (SNP) | VAF 18/43 reads (42%) | catalogued as COSV52805710; called by muse, mutect2, varscan2
- USP42 | c.442+1306C>T | Intron (SNP) | VAF 66/243 reads (27%) | called by muse, mutect2, varscan2
